Somatic mutation profile of tumor specimen 0DTB8U from CCDI case PBCJHE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 14.6 years (5,315 days).
Specimen 0DTB8U: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 602b1380-03f1-4bcf-b245-04966f7d7f8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dfdbc61-a575-402a-af6a-bf1292815b9d

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 4, Splice Region 1, RNA 1, 3'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO18B | c.7445G>A p.R2482H | Missense Mutation (SNP) | VAF 30/645 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs577931213, COSV59133306; called by muse, mutect2
- RIPOR3 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 82/762 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1199674565; called by muse, mutect2
- SLC8B1 | c.309+1G>A p.X103_splice | Splice Site (SNP) | VAF 44/676 reads (7%) | catalogued as rs755157031, COSV52527282; called by muse, mutect2
- SPEG | c.8372C>T p.P2791L | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs751025456; called by muse, mutect2, varscan2
- SYNM | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs556286004, COSV50440921; called by muse, mutect2, varscan2
- TRPC7 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as rs780636115; called by muse, mutect2, varscan2
- WDR88 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 47/437 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs775123698; called by muse, mutect2, varscan2
- C1orf158 | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DCN | c.110dup p.E39Rfs*4 | Frame Shift Ins (INS) | VAF 74/517 reads (14%) | called by mutect2, pindel, varscan2
- KMT2D | c.4540T>A p.Y1514N | Missense Mutation (SNP) | VAF 98/713 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MAGI1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 19/437 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.763); called by muse, mutect2
- MGAT4D | c.878-7T>C | Splice Region (SNP) | VAF 48/205 reads (23%) | called by muse, mutect2, varscan2
- MYO15A | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEMA5A | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 20/637 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TFEC | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 27/636 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2
- AGPAT3 | c.478A>C p.R160= | Silent (SNP) | VAF 113/1149 reads (10%) | called by muse, mutect2
- GLTP | c.357C>T p.N119= | Silent (SNP) | VAF 52/489 reads (11%) | catalogued as COSV59173244; called by muse, mutect2, varscan2
- HAPLN2 | c.504G>A p.Q168= | Silent (SNP) | VAF 66/442 reads (15%) | called by muse, mutect2, varscan2
- RCL1 | c.1059G>T p.G353= | Silent (SNP) | VAF 73/358 reads (20%) | called by mutect2, varscan2
- SPIN2B | c.684C>A p.V228= | Silent (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- CA1 | c.513+80A>G | Intron (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- KBTBD11 | c.*34G>C | 3'UTR (SNP) | VAF 26/152 reads (17%) | called by muse, mutect2, varscan2
- MARK1 | c.910-97T>C | Intron (SNP) | VAF 12/134 reads (9%) | catalogued as rs1303123525; called by muse, mutect2
- POGLUT2 | c.672+66C>G | Intron (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- SSPOP | n.5356C>T | RNA (SNP) | VAF 13/310 reads (4%) | catalogued as rs1162893946; called by muse, mutect2
- TBC1D10A | c.310-75C>T | Intron (SNP) | VAF 13/64 reads (20%) | catalogued as rs141507505; called by muse, mutect2, varscan2
